Somatic mutation profile of tumor specimen MMRF_1897_1_BM_CD138pos (aliquot MMRF_1897_1_BM_CD138pos_T3_KBS5U_L05844) from MMRF case MMRF_1897, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.6 years (21,041 days).
Specimen MMRF_1897_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbc7a82d-cc3e-4f7c-be6b-55547745393b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1897_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1897_1_PB_CD3pos_C5_KBS5U_L05816; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d935f8f5-8187-4818-a3d4-5c634f21785c

The open-access MAF lists 17 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 3'UTR 5, Silent 3, 5'UTR 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRTAP13-2 | c.197G>A p.C66Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV101299679, COSV67761876; called by muse, mutect2, varscan2
- CWH43 | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2
- GCN1 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLT8D1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- LTBP2 | c.2897del p.G966Dfs*44 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- PLEKHA4 | c.1904G>T p.R635M | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2
- TTN | c.55852G>C p.D18618H (on ENST00000591111; = p.D11194H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- AC005324.2 | c.426C>T p.C142= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- FBLN2 | c.846G>A p.E282= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs765129516, COSV104404406, COSV55481875; called by mutect2, varscan2
- PDZRN4 | c.972T>C p.A324= (on ENST00000402685 / NM_001164595.2; = p.A66= on NM_013377.4) | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- CCDC110 | c.115+263A>C | Intron (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- GCC2 | c.*448T>C | 3'UTR (SNP) | VAF 3/22 reads (14%) | catalogued as rs2378152; called by muse, mutect2
- HOXB8 | c.*475_*480del | 3'UTR (DEL) | VAF 5/24 reads (21%) | catalogued as rs948734526; called by mutect2, pindel
- HOXC11 | c.*237C>T | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- KLF7 | c.*5849T>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | catalogued as rs973513897, COSV58746863; called by muse, mutect2
- SLC33A1 | c.*97C>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- TRAK1 | c.-82G>A | 5'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
